Gene-level copy-number profile of tumor specimen TCGA-2F-A9KP-01A from TCGA case TCGA-2F-A9KP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.9 years (24,428 days).
Specimen TCGA-2F-A9KP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.5a456ee8-0991-45be-92d8-d30f8ec0455c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2F-A9KP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17f85d17-76ee-4d5f-b376-464788257827

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 5,144; copy number 3: 9,750; copy number 4: 33,616; copy number 5: 9,041; copy number 6: 1,200; copy number 7: 207; copy number 8: 174; copy number 9: 44; copy number 10: 238; copy number 11: 152; copy number 12: 98; copy number 15: 34; copy number 21: 7; copy number 22: 52; copy number 31: 18; copy number 38: 15; copy number 143: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2F-A9KP-01A-11D-A38F-01): tumor purity 0.64, ploidy 3.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 660 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,415,802–26,857,604, 95 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:28,812,142–30,141,607, 21 genes, copy number 10: OPRD1, AL009181.1, Y_RNA, EPB41, AL138785.1, Y_RNA, Metazoa_SRP, TMEM200B, AL357500.1, SRSF4, AL357500.2, MECR, AL590729.1, PTPRU, LINC01756, AL671862.1, AC092265.1, AL645944.2, AL645944.1, LINC01648, AL137076.1.
- chr1:38,859,912–38,965,038, 1 gene, copy number 11 (within-gene range 3–11): AL139260.1.
- chr1:38,885,807–40,667,480, 67 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).
- chr1:41,506,365–43,705,518, 67 genes, copy number 10–12 (broad region; genes not listed).
- chr1:43,685,123–43,708,138, 1 gene, copy number 10: KDM4A-AS1.
- chr1:43,709,392–43,743,741, 3 genes, copy number 10: ST3GAL3-AS1, U6, AL451062.1.
- chr1:160,945,025–161,309,968, 28 genes, copy number 11 (within-gene range 7–11): ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ.
- chr3:11,859,674–12,664,125, 20 genes, copy number 9–12 (within-gene range 6–12): FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1.
- chr8:40,104,169–43,544,057, 88 genes, copy number 12–21 (broad region; genes not listed).
- chr14:27,612,577–27,639,636, 2 genes, copy number 143: LINC00645, MIR3171.
- chr17:8,088,056–8,630,761, 37 genes, copy number 9: MIR4314, ALOXE3, HES7, PER1, MIR6883, AC129492.3, VAMP2, TMEM107, SNORD118, AC129492.4, MIR4521, BORCS6, AC129492.6, AC129492.5, AURKB, LINC00324, CTC1, PFAS, AC135178.6, SLC25A35, RANGRF, AC135178.7, ARHGEF15, AC135178.2, AC135178.1, AC135178.5, ODF4, KRBA2, AC135178.4, AC135178.3, RPL26, RNF222, NDEL1, MYH10, RNU7-43P, PPIAP52, AC025518.1.
- chr17:28,041,737–29,180,398, 90 genes, copy number 11–15 (within-gene range 5–15) (broad region; genes not listed).
- chr17:39,671,122–39,864,312, 6 genes, copy number 38 (within-gene range 5–38): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr20:32,632,183–34,311,802, 55 genes, copy number 10 (within-gene range 8–10): FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2.
- chr20:42,072,752–45,376,798, 79 genes, copy number 22–38 (within-gene range 6–38) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
